Somatic mutation profile of tumor specimen ALCH-B34N-TTP1-A (aliquot ALCH-B34N-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B34N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.9 years (25,538 days).
Specimen ALCH-B34N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1323326f-9e2d-4ef8-b9e1-8cf5b20333b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34N-NB1-A (Blood Derived Normal), aliquot ALCH-B34N-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5602e60-87b3-4eea-a481-2370b8c642eb

The open-access MAF lists 548 somatic variants for this specimen: 364 protein-altering or splice-affecting, 108 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 314, Silent 108, Intron 33, Nonsense Mutation 17, Splice Site 16, 5'UTR 12, 3'UTR 10, RNA 10, Frame Shift Del 8, Splice Region 6, 5'Flank 6, 3'Flank 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A2 | c.3544G>T p.G1182C | Missense Mutation (SNP) | VAF 93/560 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as rs1057524163; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 124/745 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PHEX | c.1999G>T p.G667* | Nonsense Mutation (SNP) | VAF 106/559 reads (19%) | catalogued as rs193922457, COSV101039598; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 50/296 reads (17%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- AADAT | c.766A>G p.I256V | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.277); catalogued as COSV100528676; called by muse, mutect2, varscan2
- ABCA13 | c.10336G>C p.E3446Q | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71294239; called by muse, mutect2, varscan2
- ABCB11 | c.3262C>A p.P1088T | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55601223; called by muse, mutect2, varscan2
- AC024598.1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as rs371278525, COSV60824183; called by muse, mutect2, varscan2
- ADAM17 | c.1700G>C p.C567S | Missense Mutation (SNP) | VAF 60/664 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1186144392; called by muse, mutect2
- ADAMTS20 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs774122536, COSV67138089; called by muse, mutect2, varscan2
- ARRDC3 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 229/1292 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV54366434; called by muse, mutect2, varscan2
- ATP10A | c.2645del p.G882Afs*34 | Frame Shift Del (DEL) | VAF 56/261 reads (21%) | catalogued as COSV63522480; called by mutect2, pindel, varscan2
- ATXN2L | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs769858391; called by mutect2, varscan2
- C5orf15 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201230410; called by muse, mutect2, varscan2
- CCDC141 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69459015; called by muse, mutect2, varscan2
- CERS2 | c.1138G>T p.D380Y | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as rs955626155; called by muse, mutect2, varscan2
- CNTN5 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 89/763 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.069); catalogued as rs767487705; called by muse, mutect2, varscan2
- COL11A1 | c.760C>G p.Q254E | Missense Mutation (SNP) | VAF 132/785 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.9); catalogued as COSV62188721; called by muse, mutect2, varscan2
- CPNE6 | c.863C>A p.T288K | Missense Mutation (SNP) | VAF 74/425 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53742506; called by muse, mutect2, varscan2
- CRACR2A | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 83/461 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1219681517; called by muse, mutect2, varscan2
- CSMD2 | c.9209G>C p.C3070S | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV99589258; called by muse, mutect2, varscan2
- CUX2 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 71/427 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV99920107; called by muse, mutect2, varscan2
- DAAM2 | c.3079G>C p.V1027L (on ENST00000274867 / NM_001201427.2; = p.V1026L on NM_015345.3) | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV99226126; called by muse, mutect2, varscan2
- DDX11 | c.2036G>C p.R679T | Missense Mutation (SNP) | VAF 118/687 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99299799; called by muse, mutect2, varscan2
- DES | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 179/1050 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.434); catalogued as rs397516697, COSV64660570, COSV64661110; called by muse, mutect2, varscan2
- DNAH14 | c.7445C>T p.A2482V (on ENST00000445597; = p.A3135V on NM_001367479.1) | Missense Mutation (SNP) | VAF 76/567 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.434); catalogued as rs145100008, COSV59896162; called by muse, mutect2, varscan2
- DNAH9 | c.5842G>C p.D1948H | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.076); catalogued as rs766473434, COSV52350088; called by muse, mutect2, varscan2
- DZIP1L | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 71/436 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376878265; called by muse, mutect2, varscan2
- EIF3C | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 115/994 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs780196959, COSV59060345; called by muse, mutect2, varscan2
- ELAPOR2 | c.1315G>C p.E439Q (on ENST00000450689 / NM_001142749.3; = p.E272Q on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 123/827 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as rs767602456; called by muse, mutect2, varscan2
- ENTPD6 | c.1123A>G p.K375E | Missense Mutation (SNP) | VAF 31/376 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.257); catalogued as COSV61751425; called by muse, mutect2
- EYS | c.4046G>A p.R1349Q | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs368698537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F8 | c.4825A>G p.T1609A | Missense Mutation (SNP) | VAF 83/632 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs1269626654, CD101347, COSV100812103; called by muse, mutect2, varscan2
- FBN1 | c.3037G>T p.G1013* | Nonsense Mutation (SNP) | VAF 221/979 reads (23%) | catalogued as CM950441, CM983865; called by muse, mutect2, varscan2
- GAA | c.1853G>A p.W618* | Nonsense Mutation (SNP) | VAF 114/748 reads (15%) | catalogued as rs1384805011; called by muse, mutect2, varscan2
- GATA4 | c.1308C>A p.H436Q | Missense Mutation (SNP) | VAF 124/659 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs779684582; called by muse, mutect2, varscan2
- GHR | c.137-1G>T p.X46_splice | Splice Site (SNP) | VAF 133/1101 reads (12%) | catalogued as COSV50116721; called by muse, mutect2, varscan2
- GPR62 | c.1041G>C p.Q347H | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV59055953; called by muse, mutect2, varscan2
- GPRC6A | c.2432C>A p.P811Q | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59951433; called by muse, mutect2, varscan2
- GRAP | c.353A>T p.Y118F | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV104370338; called by muse, mutect2, varscan2
- HEATR5B | c.4325C>T p.S1442L | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV51854253; called by muse, mutect2, varscan2
- IDO2 | c.1220G>T p.G407V (on ENST00000389060; = p.G420V on NM_194294.2) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs199709416; called by muse, mutect2, varscan2
- IGHJ2 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 81/458 reads (18%) | PolyPhen benign (0.306); catalogued as rs550889758; called by muse, mutect2, varscan2
- IGKV3-20 | c.222C>A p.S74R | Missense Mutation (SNP) | VAF 203/1456 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs1065533; called by muse, mutect2, varscan2
- IL1RL2 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 84/540 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs752449321, COSV51813930, COSV51818269; called by muse, mutect2, varscan2
- IRF6 | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 38/678 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CS092372; called by muse, mutect2
- IZUMO3 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0.01); catalogued as rs757546201; called by muse, mutect2, varscan2
- KCND2 | c.767G>C p.R256P | Missense Mutation (SNP) | VAF 63/508 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV58593189; called by muse, mutect2, varscan2
- KIF13B | c.4979C>T p.S1660L | Missense Mutation (SNP) | VAF 71/441 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.038); catalogued as rs1218848641, COSV68094265; called by muse, mutect2, varscan2
- KLHL34 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344940182, COSV101070007; called by muse, mutect2, varscan2
- KMT2A | c.4697-1G>T p.X1566_splice | Splice Site (SNP) | VAF 33/180 reads (18%) | catalogued as COSV100629383; called by muse, mutect2, varscan2
- LMAN1L | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 165/450 reads (37%) | catalogued as rs757863036; called by muse, mutect2, varscan2
- LY75 | c.4427A>G p.Y1476C | Missense Mutation (SNP) | VAF 108/815 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1359281058; called by muse, mutect2, varscan2
- MAB21L1 | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 90/432 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59786473; called by muse, mutect2, varscan2
- MAPRE1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 48/184 reads (26%) | catalogued as COSV65033102; called by muse, mutect2, varscan2
- MRC2 | c.2683G>C p.E895Q | Missense Mutation (SNP) | VAF 67/470 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV57643966; called by muse, mutect2, varscan2
- MYBPH | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55139348, COSV55139640; called by muse, mutect2, varscan2
- MYT1L | c.2195C>A p.T732N | Missense Mutation (SNP) | VAF 87/521 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV67727867; called by muse, mutect2, varscan2
- NAT10 | c.2540G>T p.R847L | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs777910148, COSV57662490; called by muse, mutect2, varscan2
- NEUROD1 | c.698C>A p.T233N | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as rs1455924447; called by muse, mutect2, varscan2
- NF1 | c.5423C>T p.T1808M (on ENST00000358273 / NM_001042492.3; = p.T1787M on NM_000267.3) | Missense Mutation (SNP) | VAF 158/557 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs760649828, CM062897, COSV62217904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP14 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 136/685 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV55065161; called by muse, mutect2, varscan2
- NRIP2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1231833627; called by muse, mutect2, varscan2
- NRXN3 | c.1131G>T p.M377I | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1410088402; called by muse, mutect2, varscan2
- NRXN3 | c.1529C>A p.P510Q | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55346969; called by muse, mutect2, varscan2
- NUCB1 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs770919085; called by muse, mutect2, varscan2
- NXPE3 | c.1199A>G p.N400S | Missense Mutation (SNP) | VAF 75/412 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs376234770; called by muse, mutect2, varscan2
- OR10W1 | c.713T>C p.V238A | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1242155770; called by muse, mutect2, varscan2
- OR4D10 | c.122del p.G41Efs*77 | Frame Shift Del (DEL) | VAF 29/242 reads (12%) | catalogued as COSV73260234; called by mutect2, pindel, varscan2
- OR5AP2 | c.213C>A p.S71R | Missense Mutation (SNP) | VAF 77/477 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV57259283; called by muse, mutect2, varscan2
- OR5F1 | c.354G>C p.M118I | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53549353, COSV99558485; called by muse, mutect2, varscan2
- PAPPA2 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 85/535 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100867333, COSV62773745, COSV62780042; called by muse, mutect2, varscan2
- PDGFD | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 94/577 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs1329527406, COSV100158110, COSV56389294; called by muse, mutect2, varscan2
- PDGFRA | c.2965A>G p.I989V | Missense Mutation (SNP) | VAF 84/679 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs145019788, COSV99078760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGLYRP3 | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 40/242 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs1043074601; called by muse, mutect2
- PGP | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.363); catalogued as rs757510928; called by muse, mutect2, varscan2
- PHF6 | c.571G>C p.E191Q (on ENST00000332070 / NM_032458.3; = p.E192Q on NM_032335.3) | Missense Mutation (SNP) | VAF 86/408 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV59701471; called by muse, mutect2, varscan2
- PIK3CG | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63250049; called by muse, mutect2, varscan2
- PNRC1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 133/926 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.461); catalogued as rs771346878; called by muse, mutect2, varscan2
- PPP1R11 | c.69C>G p.P23= | Splice Region (SNP) | VAF 51/546 reads (9%) | catalogued as rs1270830582; called by muse, mutect2
- PPP1R14A | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV56646784; called by muse, mutect2, varscan2
- PTEN | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 83/408 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV64288425, COSV64299515; called by muse, mutect2, varscan2
- PYDC2 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 91/666 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs777803468; called by muse, mutect2, varscan2
- RB1CC1 | c.4441A>G p.M1481V | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as rs746678654; called by mutect2, varscan2
- RRM1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.583); catalogued as rs753295405; called by muse, mutect2, varscan2
- RYR2 | c.14578G>T p.A4860S | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100772946; called by muse, mutect2
- S1PR5 | c.995C>A p.P332Q | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1182164627, COSV100330670; called by muse, mutect2, varscan2
- SEPTIN4 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs764453112; called by muse, mutect2, varscan2
- SERPINH1 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.427); catalogued as COSV63997803; called by muse, mutect2, varscan2
- SLAMF1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 96/552 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as rs775569782; called by muse, mutect2, varscan2
- SLC18A3 | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234862486; called by muse, mutect2, varscan2
- SLC35G6 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 193/825 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.193); catalogued as rs756447150; called by muse, mutect2, varscan2
- SLCO1B1 | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 143/758 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs773226433; called by muse, mutect2, varscan2
- SMC2 | c.3111G>A p.V1037= | Splice Region (SNP) | VAF 32/146 reads (22%) | catalogued as rs1019635349; called by muse, mutect2, varscan2
- SRD5A2 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 88/585 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs369117426, COSV51871710; called by muse, mutect2, varscan2
- SVIL | c.4039G>A p.E1347K (on ENST00000355867 / NM_021738.3; = p.E921K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV63442036; called by muse, mutect2
- SYT14 | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 112/623 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV55054451; called by muse, mutect2, varscan2
- TAF1C | c.2082G>C p.Q694H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.66); catalogued as rs754970030; called by muse, mutect2, varscan2
- TAF1L | c.1947G>T p.Q649H | Missense Mutation (SNP) | VAF 99/478 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV54263526; called by mutect2, varscan2
- TBX3 | c.1388C>T p.A463V (on ENST00000257566 / NM_016569.4; = p.A443V on NM_005996.4) | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1247378046, COSV99983364; called by muse, mutect2, varscan2
- TCL1A | c.96C>A p.H32Q | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV68085600; called by muse, mutect2, varscan2
- THSD7A | c.2597A>C p.Q866P | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV70262344; called by muse, mutect2, varscan2
- TLL2 | c.2054C>A p.S685Y | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs759116246; called by muse, mutect2, varscan2
- TMEM63C | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 87/669 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as rs1224982578, COSV100029033; called by muse, mutect2, varscan2
- TMTC1 | c.1813T>C p.Y605H (on ENST00000539277 / NM_001193451.2; = p.Y497H on NM_175861.3) | Missense Mutation (SNP) | VAF 70/480 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs1315922445; called by muse, mutect2, varscan2
- TOMM22 | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53265836; called by muse, mutect2, varscan2
- TRIM48 | c.217A>C p.K73Q | Missense Mutation (SNP) | VAF 124/789 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs753404269; called by muse, mutect2, varscan2
- USP37 | c.1330A>G p.M444V | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs892574360; called by muse, mutect2, varscan2
- WWP2 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs1359990568, COSV63123924; called by muse, mutect2, varscan2
- XKR6 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 104/467 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58655056; called by muse, mutect2, varscan2
- XRN1 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 36/186 reads (19%) | catalogued as COSV53813325; called by muse, mutect2, varscan2
- ZNF720 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV57178751; called by muse, mutect2, varscan2
- ABCA8 | c.1694A>C p.Q565P | Missense Mutation (SNP) | VAF 77/633 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABHD12B | c.349A>T p.S117C (on ENST00000337334 / NM_001206673.2; = p.S40C on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- AC068633.1 | n.297+1G>A | Splice Site (SNP) | VAF 47/313 reads (15%) | called by muse, mutect2, varscan2
- AC104452.1 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 146/908 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- AC244197.3 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 164/928 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ACACB | c.4747A>C p.T1583P | Missense Mutation (SNP) | VAF 91/530 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ACE2 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ACHE | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 87/543 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS15 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 59/359 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS2 | c.1417C>A p.H473N | Missense Mutation (SNP) | VAF 53/435 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- ADAMTS20 | c.3824T>G p.V1275G | Missense Mutation (SNP) | VAF 164/909 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGB | c.4928C>G p.A1643G | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ADGRL3 | c.2335del p.E779Kfs*3 (on ENST00000506720 / NM_001322402.2; = p.E711Kfs*3 on NM_015236.6) | Frame Shift Del (DEL) | VAF 71/575 reads (12%) | called by mutect2, pindel, varscan2
- AGL | c.1637T>A p.L546* | Nonsense Mutation (SNP) | VAF 184/1163 reads (16%) | called by muse, mutect2, varscan2
- ALOX15B | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD13C | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 65/424 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKS1A | c.1642G>A p.G548S | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- ARG1 | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 84/571 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ARSF | c.1731A>T p.E577D | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by mutect2, varscan2
- ASMT | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 85/380 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ATP4A | c.2340C>A p.F780L | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP8B2 | c.1042G>A p.A348T (on ENST00000672630; = p.A315T on NM_001005855.2) | Missense Mutation (SNP) | VAF 106/646 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BRINP2 | c.911C>A p.P304H | Missense Mutation (SNP) | VAF 139/944 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- BST1 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 78/461 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1QTNF8 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CALCOCO1 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 100/521 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CASP12 | c.614_615insAG p.S206Gfs*3 | Frame Shift Ins (INS) | VAF 50/436 reads (11%) | called by muse*, mutect2
- CASP12 | c.612_613del p.C204* | Nonsense Mutation (DEL) | VAF 53/458 reads (12%) | called by muse*, mutect2
- CASR | c.2731del p.A911Pfs*20 (on ENST00000490131; = p.A988Pfs*20 on NM_000388.4) | Frame Shift Del (DEL) | VAF 149/944 reads (16%) | called by mutect2, pindel, varscan2
- CCDC185 | c.40G>T p.D14Y | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CDH2 | c.2557G>T p.D853Y | Missense Mutation (SNP) | VAF 93/452 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDKN1C | c.821-1G>A p.X274_splice | Splice Site (SNP) | VAF 32/145 reads (22%) | called by muse, mutect2, varscan2
- CEP164 | c.4096+1G>A p.X1366_splice | Splice Site (SNP) | VAF 73/492 reads (15%) | called by muse, mutect2, varscan2
- CFAP61 | c.1245+1G>T p.X415_splice | Splice Site (SNP) | VAF 72/376 reads (19%) | called by muse, mutect2, varscan2
- CHD4 | c.4862A>C p.E1621A (on ENST00000357008 / NM_001363606.2; = p.E1634A on NM_001273.5) | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHM | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 82/491 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHRDL2 | c.1207C>G p.H403D (on ENST00000376332 / NM_001304415.1; = p.P421R on NM_015424.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- CITED2 | c.437T>A p.M146K | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CLIP1 | c.457A>T p.T153S | Missense Mutation (SNP) | VAF 114/332 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP4 | c.1039T>C p.S347P | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLMN | c.2769G>T p.S923= | Splice Region (SNP) | VAF 75/446 reads (17%) | called by muse, mutect2, varscan2
- CMKLR1 | c.664G>T p.V222F (on ENST00000312143 / NM_001142344.2; = p.V220F on NM_004072.3) | Missense Mutation (SNP) | VAF 15/534 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2
- CNBD1 | c.518A>T p.K173M | Missense Mutation (SNP) | VAF 56/348 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- CNTN1 | c.1999A>T p.R667* | Nonsense Mutation (SNP) | VAF 56/351 reads (16%) | called by muse, mutect2, varscan2
- COL11A2 | c.3841G>A p.G1281S (on ENST00000341947 / NM_080680.3; = p.G1174S on NM_080679.2) | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL3A1 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 123/815 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- COL5A1 | c.3323G>T p.G1108V | Missense Mutation (SNP) | VAF 73/290 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COQ3 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CSMD1 | c.10637C>A p.P3546H (on ENST00000520002; = p.P3545H on NM_033225.6) | Missense Mutation (SNP) | VAF 58/408 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CSMD1 | c.8703G>C p.Q2901H (on ENST00000520002; = p.Q2900H on NM_033225.6) | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CTNNA2 | c.211T>A p.F71I | Missense Mutation (SNP) | VAF 82/599 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CTNNB1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 215/1159 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYP4A22 | c.759C>A p.H253Q | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DAAM2 | c.1628C>A p.P543H | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- DMBT1 | c.5993G>A p.G1998D (on ENST00000338354 / NM_001377530.1; = p.G1241D on NM_004406.3) | Missense Mutation (SNP) | VAF 114/476 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- DMRTA2 | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DYNC1H1 | c.13496G>C p.G4499A | Missense Mutation (SNP) | VAF 54/1030 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2
- E2F7 | c.2455C>T p.Q819* | Nonsense Mutation (SNP) | VAF 145/868 reads (17%) | called by muse, mutect2, varscan2
- EDEM3 | c.1658T>C p.V553A | Missense Mutation (SNP) | VAF 60/349 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- EGFL7 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- EIF3B | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF3CL | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by mutect2, varscan2
- EOLA1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 124/771 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- EPB41L4A | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 72/451 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EPPK1 | c.4337C>A p.T1446N | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERBB4 | c.3189G>T p.Q1063H | Missense Mutation (SNP) | VAF 75/511 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ETAA1 | c.1978A>G p.K660E | Missense Mutation (SNP) | VAF 90/596 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.201); called by muse, varscan2
- ETV1 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYA1 | c.347C>G p.T116R | Missense Mutation (SNP) | VAF 48/620 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2
- F13B | c.1708G>T p.G570* | Nonsense Mutation (SNP) | VAF 57/326 reads (17%) | called by muse, mutect2, varscan2
- F8 | c.4826C>A p.T1609K | Missense Mutation (SNP) | VAF 83/631 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM149A | c.977T>A p.L326Q (on ENST00000356371 / NM_001367768.2; = p.L35Q on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/338 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAM186B | c.1477T>C p.W493R | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- FBXW12 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- FIBCD1 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- FIG4 | c.1198T>G p.Y400D | Missense Mutation (SNP) | VAF 95/972 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); called by muse, mutect2
- FILIP1 | c.3571C>A p.Q1191K | Missense Mutation (SNP) | VAF 111/691 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- FMR1 | c.1284C>A p.D428E | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- FNDC1 | c.4468A>G p.T1490A | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.079); called by muse, mutect2
- FSCN2 | c.871A>C p.T291P | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FSD2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRE | c.841G>T p.A281S | Missense Mutation (SNP) | VAF 73/546 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- GAL3ST3 | c.743T>C p.L248P | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GHR | c.893T>G p.L298R | Missense Mutation (SNP) | VAF 223/969 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GLUL | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 126/802 reads (16%) | called by muse, mutect2, varscan2
- GLYATL3 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 77/457 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GMPS | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPIHBP1 | c.169G>C p.G57R | Missense Mutation (SNP) | VAF 128/740 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GPR22 | c.188T>C p.L63S | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPX6 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 123/576 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- GRK7 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 110/616 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HACD1 | c.584del p.P195Hfs*34 | Frame Shift Del (DEL) | VAF 82/289 reads (28%) | called by mutect2, pindel, varscan2
- HHEX | c.553T>G p.F185V | Missense Mutation (SNP) | VAF 81/442 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHEX | c.554T>G p.F185C | Missense Mutation (SNP) | VAF 80/443 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HIP1R | c.440A>T p.H147L | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- HIVEP1 | c.2273dup p.L758Ffs*4 | Frame Shift Ins (INS) | VAF 79/415 reads (19%) | called by mutect2, pindel, varscan2
- HMG20A | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 163/493 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HMMR | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- HPSE | c.902A>C p.N301T | Missense Mutation (SNP) | VAF 105/478 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HRH1 | c.1128G>C p.L376F | Missense Mutation (SNP) | VAF 165/885 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ICAM3 | c.461T>G p.L154R | Missense Mutation (SNP) | VAF 126/514 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.3602C>T p.T1201I | Missense Mutation (SNP) | VAF 330/719 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IFT172 | c.3120G>C p.E1040D | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- IGKV3D-11 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 199/1540 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- ITGA7 | c.2044G>A p.G682S (on ENST00000555728; = p.G638S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/670 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KANSL1 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- KCNH7 | c.724A>G p.R242G | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1210 | c.1814C>A p.T605N | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KIF21A | c.1239G>T p.E413D | Missense Mutation (SNP) | VAF 138/924 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KLF17 | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 79/440 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KLHL12 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 70/545 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KPTN | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- KRT34 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 54/506 reads (11%) | called by muse, mutect2, varscan2
- LAMA2 | c.8801G>C p.C2934S | Missense Mutation (SNP) | VAF 156/1098 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LAMB2 | c.1024C>A p.H342N | Missense Mutation (SNP) | VAF 119/742 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LRRC71 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 92/506 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAGT1 | c.10C>G p.R4G (on ENST00000618282 / NM_001367916.1; = p.R36G on NM_032121.5) | Missense Mutation (SNP) | VAF 30/688 reads (4%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- MAN1C1 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MAP7 | c.526+1G>A p.X176_splice | Splice Site (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- MARK1 | c.1572C>T p.S524= | Splice Region (SNP) | VAF 36/183 reads (20%) | called by muse, varscan2
- MARK2 | c.632G>C p.G211A | Missense Mutation (SNP) | VAF 130/833 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEGF6 | c.2986G>C p.G996R | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MET | c.2032A>G p.T678A | Missense Mutation (SNP) | VAF 106/896 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.006); called by mutect2, varscan2
- MGAM | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 77/631 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- MLIP | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, varscan2
- MMD2 | c.609G>C p.M203I (on ENST00000404774 / NM_001100600.2; = p.M179I on NM_198403.4) | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- MMP26 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 101/747 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MMRN1 | c.3652A>T p.T1218S | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- MMUT | c.1809-1G>C p.X603_splice | Splice Site (SNP) | VAF 104/675 reads (15%) | called by muse, varscan2
- MSR1 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 67/447 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC12 | c.9017C>T p.S3006L (on ENST00000379442; = p.S2863L on NM_001164462.1) | Missense Mutation (SNP) | VAF 126/4090 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- MUC17 | c.5336C>G p.P1779R | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MYH13 | c.273G>C p.M91I | Missense Mutation (SNP) | VAF 110/767 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- MYH2 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 156/753 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYL1 | c.279A>T p.K93N | Missense Mutation (SNP) | VAF 26/450 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- MYO19 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYO6 | c.2071T>C p.C691R | Missense Mutation (SNP) | VAF 178/1122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYT1 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 115/545 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- NALCN | c.215T>A p.F72Y | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- NCOA6 | c.1202C>G p.A401G | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NECTIN3 | c.972T>G p.F324L | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- NECTIN3 | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 106/706 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NFKB2 | c.1585-1G>C p.X529_splice | Splice Site (SNP) | VAF 51/231 reads (22%) | called by muse, mutect2, varscan2
- NLGN1 | c.1255del p.V419Lfs*14 | Frame Shift Del (DEL) | VAF 26/241 reads (11%) | called by mutect2, pindel, varscan2
- NLRP4 | c.2925G>T p.E975D | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- NPC1L1 | c.3551C>T p.A1184V | Missense Mutation (SNP) | VAF 149/790 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NRXN1 | c.1607T>A p.I536K | Missense Mutation (SNP) | VAF 158/890 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NRXN3 | c.1211A>T p.Y404F | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- NSD1 | c.4537del p.E1513Rfs*7 | Frame Shift Del (DEL) | VAF 306/1165 reads (26%) | called by mutect2, pindel, varscan2
- NUDCD1 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 92/459 reads (20%) | called by muse, mutect2, varscan2
- NXPH1 | c.354G>T p.M118I | Missense Mutation (SNP) | VAF 80/417 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- OR10A3 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- OR10J5 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 80/481 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- OR2T2 | c.735C>A p.H245Q | Missense Mutation (SNP) | VAF 132/1432 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- OR4A15 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, varscan2
- OR52N2 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- OR5AU1 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR6K2 | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR7G2 | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- OTOL1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.19); called by muse, mutect2
- PADI6 | c.980G>A p.G327D | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PCDH7 | c.3174+3A>T | Splice Region (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2, varscan2
- PCED1B | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PCLO | c.13163C>G p.T4388S | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- PDCD4 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE3A | c.387G>C p.W129C | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- PEG3 | c.3481C>A p.Q1161K | Missense Mutation (SNP) | VAF 54/294 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PFDN2 | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHEX | c.1998G>T p.Q666H | Missense Mutation (SNP) | VAF 105/553 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PIEZO2 | c.3745G>A p.A1249T | Missense Mutation (SNP) | VAF 59/350 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- PIK3C2G | c.245A>T p.H82L | Missense Mutation (SNP) | VAF 138/550 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PITPNM1 | c.2822A>C p.Y941S | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PJA2 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PKMYT1 | c.739T>C p.C247R | Missense Mutation (SNP) | VAF 122/554 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLPP2 | c.264C>G p.F88L | Missense Mutation (SNP) | VAF 88/383 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- POGZ | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 56/439 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- POTEJ | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); called by mutect2, varscan2
- PREX1 | c.2291C>A p.A764D | Missense Mutation (SNP) | VAF 67/372 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PRKDC | c.9337-2A>T p.X3113_splice | Splice Site (SNP) | VAF 26/208 reads (13%) | called by mutect2, varscan2
- PSTPIP1 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 194/508 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTGER2 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPRK | c.316A>T p.I106F | Missense Mutation (SNP) | VAF 141/784 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- PXDNL | c.2495G>A p.C832Y | Missense Mutation (SNP) | VAF 91/528 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYGL | c.1403+8T>C | Splice Region (SNP) | VAF 98/643 reads (15%) | called by muse, mutect2, varscan2
- PYHIN1 | c.885C>A p.D295E | Missense Mutation (SNP) | VAF 67/543 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- QRICH2 | c.2488G>T p.A830S | Missense Mutation (SNP) | VAF 56/403 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- RAB39B | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 106/742 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCCD1 | c.632T>A p.V211D | Missense Mutation (SNP) | VAF 84/300 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RGS7 | c.1083-2A>T p.X361_splice | Splice Site (SNP) | VAF 89/504 reads (18%) | called by muse, mutect2, varscan2
- RIC1 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- RPL35A | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 188/1097 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- RRM2 | c.528T>G p.Y176* | Nonsense Mutation (SNP) | VAF 53/415 reads (13%) | called by muse, mutect2, varscan2
- RXFP3 | c.144G>C p.L48F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RYR2 | c.6071C>A p.T2024K | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- RYR2 | c.8971T>C p.C2991R | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.018); called by muse, mutect2
- S1PR5 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 74/353 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- SAMD4A | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 62/368 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- SCN2B | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 26/819 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2
- SCN3A | c.5291A>T p.N1764I | Missense Mutation (SNP) | VAF 157/814 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SEMA5A | c.2167G>C p.G723R | Missense Mutation (SNP) | VAF 313/1278 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SERPINE3 | c.4C>A p.P2T | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFXN2 | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SHANK1 | c.187T>A p.S63T | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SHANK2 | c.2190G>C p.R730S | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLAMF1 | c.802C>G p.H268D | Missense Mutation (SNP) | VAF 70/582 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- SLC15A4 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 80/456 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC2A5 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 75/479 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- SLC45A2 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 111/715 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC51A | c.901C>G p.L301V | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- SLC6A11 | c.1833C>A p.D611E | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLCO1A2 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SLCO4C1 | c.586A>G p.S196G | Missense Mutation (SNP) | VAF 80/473 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLIT2 | c.4364G>T p.G1455V | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMARCA4 | c.4534-1G>A p.X1512_splice | Splice Site (SNP) | VAF 112/548 reads (20%) | called by muse, mutect2, varscan2
- SMARCD1 | c.923A>G p.H308R | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- SMG7 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 70/402 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.376); called by mutect2, varscan2
- SMYD3 | c.1005G>T p.M335I (on ENST00000490107 / NM_001375962.1; = p.M276I on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/731 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SNED1 | c.2695G>T p.G899C | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNPH | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 121/690 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SOWAHA | c.1448T>C p.L483P | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAG1 | c.1418C>G p.A473G | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SPTAN1 | c.7222G>T p.E2408* | Nonsense Mutation (SNP) | VAF 134/641 reads (21%) | called by muse, mutect2, varscan2
- SPTBN2 | c.2263G>T p.D755Y | Missense Mutation (SNP) | VAF 116/720 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STK31 | c.2275-2A>G p.X759_splice | Splice Site (SNP) | VAF 62/228 reads (27%) | called by muse, mutect2, varscan2
- STON1 | c.1620C>A p.Y540* | Nonsense Mutation (SNP) | VAF 62/321 reads (19%) | called by muse, mutect2, varscan2
- STT3B | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 51/294 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STXBP5 | c.1649A>T p.E550V | Missense Mutation (SNP) | VAF 79/460 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SYT1 | c.998A>T p.K333M | Missense Mutation (SNP) | VAF 119/629 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TERT | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TEX11 | c.422C>G p.A141G (on ENST00000344304; = p.A126G on NM_031276.3) | Missense Mutation (SNP) | VAF 78/423 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- TEX14 | c.1492G>C p.D498H (on ENST00000240361 / NM_001201457.2; = p.D492H on NM_031272.5) | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- THEMIS | c.419C>A p.S140* | Nonsense Mutation (SNP) | VAF 92/797 reads (12%) | called by muse, mutect2, varscan2
- TIMP3 | c.205-1G>C p.X69_splice | Splice Site (SNP) | VAF 126/638 reads (20%) | called by muse, mutect2, varscan2
- TLCD1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- TLR2 | c.1079A>C p.K360T | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TMEM132C | c.2652G>T p.Q884H | Missense Mutation (SNP) | VAF 104/354 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM168 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2
- TMEM181 | c.593_594del p.P198Hfs*12 | Frame Shift Del (DEL) | VAF 81/497 reads (16%) | called by mutect2, pindel, varscan2
- TMEM63B | c.2222A>G p.Y741C | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TMEM81 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TMPRSS7 | c.604G>T p.D202Y (on ENST00000452346; = p.D89Y on NM_001042575.2) | Missense Mutation (SNP) | VAF 70/518 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRANK1 | c.6352G>T p.D2118Y | Missense Mutation (SNP) | VAF 105/704 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- VNN2 | c.1021A>C p.I341L | Missense Mutation (SNP) | VAF 87/460 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VPS13D | c.7645C>G p.Q2549E | Missense Mutation (SNP) | VAF 200/577 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- VWC2L | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- WDR64 | c.3135G>C p.K1045N | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ZBED9 | c.3880A>T p.S1294C | Missense Mutation (SNP) | VAF 36/552 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZDHHC15 | c.727A>T p.T243S | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.058); called by mutect2, varscan2
- ZNF202 | c.1034A>T p.E345V | Missense Mutation (SNP) | VAF 58/411 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF408 | c.1820A>T p.Y607F | Missense Mutation (SNP) | VAF 53/384 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF473 | c.1406G>C p.S469T | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF512B | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 79/574 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCB1 | c.1989A>T p.I663= | Silent (SNP) | VAF 98/648 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1641A>G p.G547= | Silent (SNP) | VAF 63/507 reads (12%) | called by muse, mutect2, varscan2
- ADAP1 | c.762G>C p.L254= | Silent (SNP) | VAF 45/286 reads (16%) | called by muse, mutect2, varscan2
- ADARB2 | c.153T>C p.P51= | Silent (SNP) | VAF 180/616 reads (29%) | catalogued as rs141430718; called by muse, mutect2, varscan2
- ADGRG4 | c.6375C>A p.S2125= | Silent (SNP) | VAF 56/241 reads (23%) | called by muse, mutect2, varscan2
- AGMO | c.534C>A p.A178= | Silent (SNP) | VAF 43/252 reads (17%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.141C>G p.A47= | Silent (SNP) | VAF 68/269 reads (25%) | called by muse, mutect2, varscan2
- APH1B | c.666C>A p.L222= | Silent (SNP) | VAF 140/1543 reads (9%) | called by muse, mutect2
- APOE | c.456G>T p.R152= | Silent (SNP) | VAF 101/480 reads (21%) | called by muse, mutect2, varscan2
- ATPAF1 | c.180C>G p.A60= (on ENST00000574428; = p.A83= on NM_022745.4) | Silent (SNP) | VAF 37/243 reads (15%) | called by muse, mutect2, varscan2
- B4GALT3 | c.1014C>T p.I338= | Silent (SNP) | VAF 134/923 reads (15%) | catalogued as rs1408097541; called by muse, mutect2, varscan2
- BEND3 | c.2130G>T p.S710= | Silent (SNP) | VAF 65/294 reads (22%) | called by muse, mutect2, varscan2
- C20orf194 | c.1572A>G p.K524= | Silent (SNP) | VAF 85/627 reads (14%) | catalogued as rs748573959; called by muse, mutect2, varscan2
- C6orf58 | c.69C>A p.S23= | Silent (SNP) | VAF 96/705 reads (14%) | called by muse, mutect2, varscan2
- CCDC180 | c.2664C>T p.N888= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as rs902025058; called by muse, mutect2, varscan2
- CCDC89 | c.147G>A p.L49= | Silent (SNP) | VAF 111/842 reads (13%) | called by muse, mutect2, varscan2
- COL22A1 | c.2571C>T p.F857= | Silent (SNP) | VAF 95/689 reads (14%) | catalogued as COSV57342923; called by muse, mutect2, varscan2
- CSGALNACT1 | c.768C>G p.L256= | Silent (SNP) | VAF 230/1350 reads (17%) | called by muse, varscan2
- CTU2 | c.267C>A p.V89= | Silent (SNP) | VAF 40/232 reads (17%) | called by muse, mutect2, varscan2
- CYP4A22 | c.885C>A p.L295= | Silent (SNP) | VAF 37/233 reads (16%) | catalogued as COSV99594492; called by muse, mutect2, varscan2
- DCAF4 | c.888A>G p.A296= | Silent (SNP) | VAF 70/455 reads (15%) | catalogued as rs544907326; called by muse, mutect2, varscan2
- DQX1 | c.384A>G p.G128= | Silent (SNP) | VAF 80/460 reads (17%) | called by muse, mutect2, varscan2
- EHD1 | c.1488G>C p.L496= | Silent (SNP) | VAF 63/501 reads (13%) | called by muse, mutect2, varscan2
- FADS6 | c.930C>T p.F310= | Silent (SNP) | VAF 51/325 reads (16%) | called by muse, mutect2, varscan2
- FAM217A | c.1143T>C p.S381= | Silent (SNP) | VAF 57/370 reads (15%) | called by muse, mutect2, varscan2
- FCRL2 | c.768G>T p.L256= | Silent (SNP) | VAF 108/544 reads (20%) | catalogued as COSV63833892; called by muse, mutect2, varscan2
- FEM1B | c.1590T>C p.N530= | Silent (SNP) | VAF 213/654 reads (33%) | called by muse, mutect2, varscan2
- FRMD4A | c.285A>G p.L95= | Silent (SNP) | VAF 58/346 reads (17%) | catalogued as rs1176065130; called by muse, mutect2, varscan2
- GBA2 | c.840C>T p.D280= | Silent (SNP) | VAF 90/489 reads (18%) | catalogued as rs372070908; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPN2 | c.243G>A p.L81= | Silent (SNP) | VAF 42/159 reads (26%) | called by muse, mutect2, varscan2
- GPR119 | c.399T>A p.S133= | Silent (SNP) | VAF 83/447 reads (19%) | called by muse, mutect2, varscan2
- HAS1 | c.1683G>A p.V561= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1162193829; called by muse, mutect2, varscan2
- HDAC9 | c.3117C>A p.A1039= (on ENST00000441542 / NM_178425.3; = p.A1036= on NM_178423.3) | Silent (SNP) | VAF 58/370 reads (16%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.363C>T p.I121= (on ENST00000394468 / NM_001039372.4; = p.I109= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/335 reads (18%) | catalogued as rs760784333, COSV59063141; called by muse, mutect2, varscan2
- HFM1 | c.108C>T p.L36= | Silent (SNP) | VAF 20/256 reads (8%) | called by muse, mutect2
- HMCN1 | c.3558A>G p.Q1186= | Silent (SNP) | VAF 90/488 reads (18%) | called by muse, mutect2, varscan2
- HOXB4 | c.54T>C p.P18= | Silent (SNP) | VAF 200/1335 reads (15%) | called by muse, mutect2, varscan2
- HRG | c.1329A>T p.P443= | Silent (SNP) | VAF 75/454 reads (17%) | called by muse, mutect2, varscan2
- IGDCC3 | c.690G>C p.S230= | Silent (SNP) | VAF 41/285 reads (14%) | catalogued as rs779173773; called by muse, mutect2, varscan2
- INSYN1 | c.471A>C p.P157= | Silent (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- KCNA1 | c.303C>T p.R101= | Silent (SNP) | VAF 158/805 reads (20%) | catalogued as rs886049509; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA3 | c.798C>T p.P266= | Silent (SNP) | VAF 35/317 reads (11%) | catalogued as COSV63901122; called by muse, mutect2, varscan2
- KCNJ5 | c.1212T>C p.D404= | Silent (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- KIF26B | c.4410G>A p.S1470= | Silent (SNP) | VAF 49/280 reads (18%) | catalogued as rs765305329, COSV100832730; called by muse, mutect2, varscan2
- KLK3 | c.615C>A p.G205= | Silent (SNP) | VAF 68/280 reads (24%) | called by muse, varscan2
- LBX2 | c.534C>G p.L178= (on ENST00000377566 / NM_001282430.2; = p.L174= on NM_001009812.2) | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs746217432; called by muse, varscan2
- LILRB2 | c.714G>A p.G238= | Silent (SNP) | VAF 68/290 reads (23%) | called by muse, varscan2
- MAPT | c.1335G>A p.R445= (on ENST00000262410 / NM_001377265.1; = p.R370= on NM_016835.4) | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- MARK2 | c.1185A>G p.V395= | Silent (SNP) | VAF 90/545 reads (17%) | called by muse, mutect2, varscan2
- MEAK7 | c.1149C>G p.A383= | Silent (SNP) | VAF 59/375 reads (16%) | catalogued as rs1464633397; called by muse, mutect2, varscan2
- MEGF6 | c.1371G>A p.P457= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs772769708; called by muse, mutect2, varscan2
- MLC1 | c.963C>A p.G321= | Silent (SNP) | VAF 122/652 reads (19%) | called by muse, varscan2
- MLIP | c.733T>C p.L245= | Silent (SNP) | VAF 58/407 reads (14%) | called by muse, varscan2
- MMP13 | c.462C>T p.T154= | Silent (SNP) | VAF 111/648 reads (17%) | called by muse, mutect2, varscan2
- MSX1 | c.516C>T p.N172= | Silent (SNP) | VAF 34/300 reads (11%) | called by muse, mutect2, varscan2
- MYO19 | c.351C>T p.V117= | Silent (SNP) | VAF 50/360 reads (14%) | called by muse, varscan2
- NDUFAF8 | c.93G>T p.A31= | Silent (SNP) | VAF 80/249 reads (32%) | called by muse, mutect2, varscan2
- NEXMIF | c.1533G>A p.L511= | Silent (SNP) | VAF 37/169 reads (22%) | called by muse, mutect2, varscan2
- NF1 | c.5424G>T p.T1808= (on ENST00000358273 / NM_001042492.3; = p.T1787= on NM_000267.3) | Silent (SNP) | VAF 155/541 reads (29%) | called by muse, mutect2, varscan2
- NISCH | c.3855G>A p.P1285= | Silent (SNP) | VAF 42/289 reads (15%) | catalogued as rs761604637, COSV58737205; called by muse, mutect2, varscan2
- NLGN2 | c.675G>A p.G225= | Silent (SNP) | VAF 119/620 reads (19%) | called by muse, mutect2, varscan2
- NOVA1 | c.675A>C p.G225= | Silent (SNP) | VAF 103/702 reads (15%) | called by muse, mutect2, varscan2
- NOX3 | c.1677T>A p.V559= | Silent (SNP) | VAF 36/231 reads (16%) | called by muse, mutect2, varscan2
- OR13G1 | c.135C>A p.A45= | Silent (SNP) | VAF 121/690 reads (18%) | catalogued as COSV62945336; called by muse, mutect2, varscan2
- OR2J2 | c.123A>T p.T41= | Silent (SNP) | VAF 32/400 reads (8%) | called by muse, mutect2
- OR4C5 | c.717C>T p.Y239= | Silent (SNP) | VAF 105/676 reads (16%) | catalogued as rs76220342; called by muse, mutect2, varscan2
- OR4D11 | c.45G>T p.L15= | Silent (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- OR52B4 | c.486A>T p.I162= | Silent (SNP) | VAF 49/235 reads (21%) | called by muse, mutect2, varscan2
- OR6V1 | c.453C>T p.F151= | Silent (SNP) | VAF 219/670 reads (33%) | called by muse, mutect2, varscan2
- PDCD6 | c.312G>A p.R104= | Silent (SNP) | VAF 101/787 reads (13%) | catalogued as COSV53776787; called by muse, mutect2, varscan2
- PDE4DIP | c.4029G>T p.R1343= | Silent (SNP) | VAF 100/834 reads (12%) | catalogued as rs781844532; called by muse, varscan2
- PEF1 | c.99A>T p.G33= | Silent (SNP) | VAF 29/164 reads (18%) | called by muse, mutect2, varscan2
- PLBD2 | c.564G>A p.Q188= | Silent (SNP) | VAF 109/368 reads (30%) | called by muse, mutect2, varscan2
- PLCH1 | c.2217C>A p.I739= (on ENST00000340059 / NM_001130960.2; = p.I751= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/200 reads (15%) | catalogued as COSV100396311; called by muse, mutect2, varscan2
- PLEK | c.705G>T p.V235= | Silent (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- PLXNA4 | c.3699G>T p.P1233= | Silent (SNP) | VAF 63/412 reads (15%) | called by muse, mutect2, varscan2
- POLE | c.3819G>C p.R1273= | Silent (SNP) | VAF 49/374 reads (13%) | called by muse, mutect2, varscan2
- POTEI | c.228C>A p.G76= | Silent (SNP) | VAF 239/1445 reads (17%) | called by muse, mutect2, varscan2
- PSMB4 | c.669C>T p.Y223= | Silent (SNP) | VAF 63/472 reads (13%) | called by muse, mutect2, varscan2
- QRFPR | c.648C>A p.T216= | Silent (SNP) | VAF 97/476 reads (20%) | called by muse, mutect2
- RASA3 | c.813T>G p.G271= | Silent (SNP) | VAF 17/348 reads (5%) | called by muse, mutect2
- ROBO3 | c.3063C>T p.T1021= | Silent (SNP) | VAF 62/479 reads (13%) | called by muse, mutect2, varscan2
- RP1L1 | c.2451G>T p.A817= | Silent (SNP) | VAF 63/273 reads (23%) | called by muse, mutect2, varscan2
- S100A3 | c.216T>C p.F72= | Silent (SNP) | VAF 52/352 reads (15%) | called by muse, mutect2, varscan2
- SEL1L3 | c.2511G>T p.G837= | Silent (SNP) | VAF 93/517 reads (18%) | called by muse, mutect2, varscan2
- SERBP1 | c.729T>C p.S243= | Silent (SNP) | VAF 36/261 reads (14%) | called by muse, mutect2, varscan2
- SHC2 | c.1251C>T p.T417= | Silent (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- SIVA1 | c.42A>G p.L14= | Silent (SNP) | VAF 65/400 reads (16%) | catalogued as rs200492089; called by muse, mutect2, varscan2
- SLC17A1 | c.558A>G p.L186= | Silent (SNP) | VAF 85/372 reads (23%) | called by muse, mutect2, varscan2
- SLC26A1 | c.768C>A p.A256= | Silent (SNP) | VAF 38/250 reads (15%) | called by muse, mutect2, varscan2
- SLC49A4 | c.1362G>A p.L454= | Silent (SNP) | VAF 91/553 reads (16%) | catalogued as COSV53748111; called by muse, mutect2, varscan2
- SMYD4 | c.2229G>A p.E743= | Silent (SNP) | VAF 97/450 reads (22%) | called by muse, mutect2, varscan2
- SYNE1 | c.12117C>G p.V4039= (on ENST00000367255 / NM_182961.4; = p.V3968= on NM_033071.3) | Silent (SNP) | VAF 104/612 reads (17%) | called by muse, mutect2, varscan2
- TECTA | c.2358G>T p.S786= | Silent (SNP) | VAF 39/274 reads (14%) | catalogued as COSV50714475; called by muse, mutect2, varscan2
- TENM4 | c.1713T>C p.Y571= | Silent (SNP) | VAF 19/499 reads (4%) | called by muse, mutect2
- THEMIS | c.420A>G p.S140= | Silent (SNP) | VAF 94/806 reads (12%) | called by muse, mutect2, varscan2
- TMEM132D | c.2166C>A p.P722= | Silent (SNP) | VAF 47/321 reads (15%) | catalogued as rs772601498; called by muse, mutect2, varscan2
- TMEM132D | c.1974G>A p.V658= | Silent (SNP) | VAF 80/581 reads (14%) | catalogued as COSV101243112; called by muse, mutect2, varscan2
- TMPPE | c.213C>G p.L71= | Silent (SNP) | VAF 59/296 reads (20%) | called by muse, mutect2, varscan2
- TNIP2 | c.861G>T p.T287= | Silent (SNP) | VAF 55/196 reads (28%) | catalogued as rs781597027, COSV59569890; called by muse, mutect2, varscan2
- TRIM28 | c.1266C>G p.P422= | Silent (SNP) | VAF 101/430 reads (23%) | called by muse, mutect2, varscan2
- TUBA4A | c.1011C>A p.T337= | Silent (SNP) | VAF 79/448 reads (18%) | called by muse, mutect2, varscan2
- TULP4 | c.3171C>T p.A1057= | Silent (SNP) | VAF 53/290 reads (18%) | called by muse, mutect2, varscan2
- USH2A | c.5538G>T p.L1846= | Silent (SNP) | VAF 73/419 reads (17%) | called by muse, mutect2, varscan2
- VAV2 | c.1671T>C p.C557= (on ENST00000371850 / NM_001134398.2; = p.C547= on NM_003371.4) | Silent (SNP) | VAF 76/350 reads (22%) | called by muse, mutect2, varscan2
- XYLT1 | c.174C>T p.P58= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1411086188; called by muse, mutect2
- ZFHX4 | c.2703G>A p.L901= | Silent (SNP) | VAF 55/688 reads (8%) | called by muse, mutect2
- ZNF831 | c.60T>A p.T20= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- ABHD4 | chr14:22598164 G>A | 5'Flank (SNP) | VAF 37/271 reads (14%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+7949G>C | Intron (SNP) | VAF 27/846 reads (3%) | called by muse, mutect2
- AC068587.7 | chr8:12659660 C>G | 5'Flank (SNP) | VAF 49/498 reads (10%) | called by muse, varscan2
- AC107023.1 | n.26-11355G>T | Intron (SNP) | VAF 41/363 reads (11%) | called by muse, mutect2, varscan2
- ACOXL | c.789-21978A>T | Intron (SNP) | VAF 96/685 reads (14%) | called by muse, mutect2, varscan2
- ADAM15 | c.1918-37T>C | Intron (SNP) | VAF 87/518 reads (17%) | called by muse, mutect2, varscan2
- ADPGK | chr15:72783836 G>C | 5'Flank (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663480 C>A | 3'Flank (SNP) | VAF 68/350 reads (19%) | called by muse, mutect2
- ANTXR1 | c.643-38A>T | Intron (SNP) | VAF 116/632 reads (18%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501869 G>T | 5'Flank (SNP) | VAF 68/407 reads (17%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500791 T>A | 5'Flank (SNP) | VAF 128/877 reads (15%) | called by muse, mutect2, varscan2
- ATRNL1 | c.-264G>T | 5'UTR (SNP) | VAF 64/267 reads (24%) | called by muse, mutect2, varscan2
- AXIN2 | c.*1337T>G | 3'UTR (SNP) | VAF 30/154 reads (19%) | called by muse, varscan2
- BMS1P15 | n.423A>G | RNA (SNP) | VAF 60/395 reads (15%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700540 A>T | 3'Flank (SNP) | VAF 32/942 reads (3%) | called by muse, mutect2
- C4A | chr6:32006469 C>G | 3'Flank (SNP) | VAF 73/984 reads (7%) | called by muse, mutect2
- CACNB4 | c.699+250G>T | Intron (SNP) | VAF 82/428 reads (19%) | catalogued as rs1559899128; called by muse, mutect2, varscan2
- CCDC140 | n.794G>A | RNA (SNP) | VAF 64/333 reads (19%) | catalogued as COSV99735133; called by muse, mutect2, varscan2
- CGREF1 | chr2:27100437 C>T | 3'Flank (SNP) | VAF 76/362 reads (21%) | called by muse, mutect2, varscan2
- CHMP6 | chr17:81004569 G>C | 3'Flank (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- CKAP2L | c.-5G>C | 5'UTR (SNP) | VAF 80/499 reads (16%) | called by muse, mutect2, varscan2
- COL6A3 | c.6592-30T>G | Intron (SNP) | VAF 38/272 reads (14%) | called by muse, mutect2, varscan2
- CPED1 | c.540+3875A>G | Intron (SNP) | VAF 48/386 reads (12%) | called by muse, mutect2, varscan2
- CYP11B1 | c.1122-31G>A | Intron (SNP) | VAF 66/443 reads (15%) | catalogued as rs749627330; called by muse, mutect2, varscan2
- DBP | c.550+67G>C | Intron (SNP) | VAF 32/144 reads (22%) | called by muse, varscan2
- DDX1 | c.1876-46G>T | Intron (SNP) | VAF 60/344 reads (17%) | called by muse, mutect2, varscan2
- DHRS9 | c.-441C>T | 5'UTR (SNP) | VAF 62/304 reads (20%) | called by muse, varscan2
- EPHA8 | c.1315+128C>A | Intron (SNP) | VAF 71/167 reads (43%) | catalogued as rs762939441, COSV99384215; called by muse, mutect2, varscan2
- EXOC4 | c.1418-53175C>T | Intron (SNP) | VAF 19/191 reads (10%) | catalogued as rs774924677; called by muse, varscan2
- FAM27E5 | n.263C>T | RNA (SNP) | VAF 59/226 reads (26%) | catalogued as rs377739235; called by muse, mutect2, varscan2
- GRIA4 | c.1269+1392C>A | Intron (SNP) | VAF 37/186 reads (20%) | catalogued as rs867607081, COSV99230543; called by muse, mutect2, varscan2
- HOOK3 | c.1533-3104A>C | Intron (SNP) | VAF 41/299 reads (14%) | catalogued as COSV56879509; called by muse, mutect2, varscan2
- KCNK2 | c.-27G>C | 5'UTR (SNP) | VAF 54/299 reads (18%) | called by muse, mutect2, varscan2
- LINC02337 | n.40-15642A>T | Intron (SNP) | VAF 38/202 reads (19%) | called by muse, mutect2, varscan2
- LYZ | c.-4C>G | 5'UTR (SNP) | VAF 124/844 reads (15%) | called by muse, mutect2, varscan2
- MAGEA5 | n.22C>A | RNA (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- MAN2B1 | c.1645-37G>C | Intron (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- MAP3K14 | c.1553-52G>A | Intron (SNP) | VAF 109/655 reads (17%) | catalogued as rs1207987127; called by muse, mutect2, varscan2
- MAPKAPK2 | c.-21G>T | 5'UTR (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- MIR520E | n.21G>C | RNA (SNP) | VAF 86/439 reads (20%) | called by muse, mutect2, varscan2
- MIR522 | n.5A>T | RNA (SNP) | VAF 78/344 reads (23%) | called by muse, mutect2, varscan2
- MKS1 | c.645-9G>T | Intron (SNP) | VAF 113/614 reads (18%) | called by muse, mutect2, varscan2
- MOB4 | c.60+25C>T | Intron (SNP) | VAF 100/604 reads (17%) | catalogued as rs1382588020; called by muse, mutect2, varscan2
- NEB | c.11602-3080T>A | Intron (SNP) | VAF 117/766 reads (15%) | called by muse, mutect2, varscan2
- NEXN | c.*43A>G | 3'UTR (SNP) | VAF 107/521 reads (21%) | called by muse, mutect2, varscan2
- NPHS2 | c.874-13A>T | Intron (SNP) | VAF 52/338 reads (15%) | called by muse, mutect2, varscan2
- NPIPB10P | n.1242G>T | RNA (SNP) | VAF 28/162 reads (17%) | called by mutect2, varscan2
- NTM-AS1 | n.2460C>A | RNA (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- PLEKHM1P1 | n.1161C>T | RNA (SNP) | VAF 119/614 reads (19%) | catalogued as rs978343352; called by muse, mutect2, varscan2
- PNCK | chrX:153674088 C>A | 5'Flank (SNP) | VAF 85/578 reads (15%) | called by muse, mutect2, varscan2
- PNPO | c.138+12A>G | Intron (SNP) | VAF 30/151 reads (20%) | called by muse, mutect2
- PRSS27 | c.678+92C>G | Intron (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2
- PUSL1 | c.-21C>T | 5'UTR (SNP) | VAF 85/230 reads (37%) | catalogued as rs1263069375; called by muse, mutect2, varscan2
- RAB18 | c.*3560G>T | 3'UTR (SNP) | VAF 103/629 reads (16%) | called by mutect2, varscan2
- RASA1 | c.2184+49T>A | Intron (SNP) | VAF 56/375 reads (15%) | called by muse, mutect2, varscan2
- RBBP4 | c.-42G>A | 5'UTR (SNP) | VAF 48/252 reads (19%) | catalogued as rs771854989; called by muse, mutect2, varscan2
- RCC1 | c.-315C>G | 5'UTR (SNP) | VAF 64/676 reads (9%) | called by muse, mutect2
- RPF1 | c.-2C>A | 5'UTR (SNP) | VAF 19/116 reads (16%) | catalogued as rs777882400; called by muse, mutect2, varscan2
- SDHAP1 | n.1449C>A | RNA (SNP) | VAF 123/1158 reads (11%) | called by muse, mutect2, varscan2
- SGIP1 | c.472-1134C>T | Intron (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*45C>G | 3'UTR (SNP) | VAF 143/682 reads (21%) | catalogued as COSV54227232; called by muse, mutect2, varscan2
- SMC2 | c.3269+1296A>T | Intron (SNP) | VAF 68/341 reads (20%) | called by muse, mutect2, varscan2
- SOGA1 | c.*8776C>A | 3'UTR (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- SSUH2 | c.-3-650C>G | Intron (SNP) | VAF 128/710 reads (18%) | called by muse, mutect2, varscan2
- TBC1D20 | c.-73C>T | 5'UTR (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- TMEM63A | c.746+12G>T | Intron (SNP) | VAF 59/306 reads (19%) | called by muse, mutect2, varscan2
- TNFAIP2 | c.*613C>A | 3'UTR (SNP) | VAF 37/197 reads (19%) | called by muse, mutect2
- TNFAIP2 | c.*614C>A | 3'UTR (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2
- TPK1 | c.613+17388T>A | Intron (SNP) | VAF 62/464 reads (13%) | called by muse, varscan2
- TPM3 | c.642+468_642+500del | Intron (DEL) | VAF 86/566 reads (15%) | called by mutect2, pindel
- TTBK2 | c.823-7106A>G | Intron (SNP) | VAF 106/482 reads (22%) | catalogued as rs1217246548; called by muse, mutect2, varscan2
- UQCRB | c.*4163C>T | 3'UTR (SNP) | VAF 101/478 reads (21%) | catalogued as rs761801179; called by muse, mutect2, varscan2
- UQCRB | c.*3657C>A | 3'UTR (SNP) | VAF 44/1274 reads (3%) | called by muse, mutect2
- VRK2 | c.*149C>G | 3'UTR (SNP) | VAF 39/197 reads (20%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+3603G>C | Intron (SNP) | VAF 38/241 reads (16%) | called by muse, mutect2, varscan2
- ZPBP | c.-8G>T | 5'UTR (SNP) | VAF 68/488 reads (14%) | called by muse, mutect2, varscan2
